Gene-level copy-number profile of tumor specimen HCM-STAN-0848-C20-01A from HCMI case HCM-STAN-0848-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen HCM-STAN-0848-C20-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 90e4c6c5-b9b4-431a-bfa2-06cee7381544.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0848-C20-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,754 have no estimate.
https://portal.gdc.cancer.gov/files/0492dffb-e184-4e9b-8d07-693cceac8a49

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 70; copy number 2: 7,163; copy number 3: 2,160; copy number 4: 39,928; copy number 5: 1,568; copy number 6: 4,462; copy number 7: 2,159; copy number 9: 681; copy number 10: 658; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:88,465,778–88,555,007, 4 genes (within-gene range 0–2): PTPN21, AL162171.2, RNU4-22P, AL162171.1.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–2): RNU6-457P.
- chr18:50,879,080–51,085,045, 5 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,340 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene, copy number 14: ADAM3A.
- chr13:18,609,132–114,337,626, 1,327 genes, copy number 9–10 (broad region; genes not listed).
- chr15:30,170,563–30,254,508, 4 genes, copy number 9: AC120045.1, LINC02249, AC135731.1, RNU6-17P.
- chr15:30,344,307–30,420,429, 8 genes, copy number 10: AC019322.4, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2.

Autosomal genes at a single copy (total copy number 1): 70. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
